TCGA case TCGA-A6-2671 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/565e2726-4942-4726-89d3-c5e3797f7204

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 85 years; Vital status: Dead; Days to death: 1,331 days (3.6 years).

Diagnoses (4)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 85.8 years (31,329 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,331 days (3.6 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 27; Lymphatic invasion present: Yes; Non nodal tumor deposits: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Palliative; Days to treatment start: 96 days; Days to treatment end: 270 days; Number of cycles: 12; Treatment dose: 3,620 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Conatumumab; Treatment intent type: Palliative; Days to treatment start: 96 days; Days to treatment end: 270 days; Number of cycles: 12; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Palliative; Days to treatment start: 96 days; Days to treatment end: 272 days; Number of cycles: 12; Treatment dose: 42,950 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Palliative; Days to treatment start: 96 days; Days to treatment end: 270 days; Number of cycles: 12; Treatment dose: 7,185 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Treatment intent type: Palliative; Days to treatment start: 96 days; Days to treatment end: 270 days; Number of cycles: 12; Treatment dose: 8,435 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Treatment intent type: Palliative; Days to treatment start: 96 days; Days to treatment end: 186 days; Number of cycles: 7; Treatment dose: 985 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 551 days (1.5 years); Days to treatment end: 739 days (2.0 years); Number of cycles: 12; Treatment dose: 3,775 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 551 days (1.5 years); Number of cycles: 7; Treatment dose: 2,200 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Initial disease status: Progressive Disease; Days to treatment start: 551 days (1.5 years); Days to treatment end: 756 days (2.1 years); Number of cycles: 13; Treatment dose: 56,000 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Initial disease status: Progressive Disease; Days to treatment start: 551 days (1.5 years); Number of cycles: 7; Treatment dose: 5,075 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 725; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Initial disease status: Progressive Disease; Days to treatment start: 551 days (1.5 years); Days to treatment end: 754 days (2.1 years); Number of cycles: 13; Treatment dose: 9,425 mg; Prescribed dose: 725; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Initial disease status: Progressive Disease; Days to treatment start: 551 days (1.5 years); Number of cycles: 7; Treatment dose: 30,200 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 551 days (1.5 years); Number of cycles: 7; Treatment dose: 2,250 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 551 days (1.5 years); Days to treatment end: 711 days (1.9 years); Number of cycles: 9; Treatment dose: 2,890 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Initial disease status: Progressive Disease; Days to treatment start: 725 days (2.0 years); Days to treatment end: 754 days (2.1 years); Number of cycles: 3; Treatment dose: 1,500 mg; Prescribed dose: 500; Prescribed dose units: mg; Route of administration: Intravesical.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Days to treatment start: 844 days (2.3 years); Days to treatment end: 984 days (2.7 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 844 days (2.3 years); Days to treatment end: 844 days (2.3 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 844 days (2.3 years); Days to treatment end: 846 days (2.3 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Days to treatment start: 844 days (2.3 years); Days to treatment end: 984 days (2.7 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 844 days (2.3 years); Days to treatment end: 844 days (2.3 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Cetuximab; Days to treatment start: 1,041 days (2.9 years); Days to treatment end: 1,091 days (3.0 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Days to treatment start: 1,041 days (2.9 years); Days to treatment end: 1,105 days (3.0 years); Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 87.2 years (31,864 days); Days to diagnosis: 535 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 88.0 years (32,159 days); Days to diagnosis: 830 days (2.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.
4. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 89.1 years (32,544 days); Days to diagnosis: 1,215 days (3.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (7 entries)
- Day 535 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 535 days (1.5 years).
- Days to follow up: 648 days (1.8 years); Disease response: With Tumor.
- Days to follow up: 802 days (2.2 years); Disease response: With Tumor.
- Day 830 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 830 days (2.3 years).
- Days to follow up: 1,126 days (3.1 years); Disease response: With Tumor.
- Day 1,215 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,215 days (3.3 years).
- Days to follow up: 1,331 days (3.6 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 17.4 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 67.2 kg; Height: 182.8 cm; BMI: 20.1.
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-A6-2671-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.8; Intermediate dimension: 0.6; Shortest dimension: 0.6.
  Slide TCGA-A6-2671-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-A6-2671-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 70; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 15.
- Sample TCGA-A6-2671-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-A6-2671-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-A6-2671-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.8; Intermediate dimension: 0.7; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 17.4; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Colon polyps at procurement indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Study drug AMG 655.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: 5 FU.
- Drug treatment 3: Regimen number: 1; Therapy regimen: Progression.
- Drug treatment 5: Regimen number: 2; Pharmaceutical therapy drug name: 5 FU; Therapy regimen: Progression.
- Drug treatment 6: Regimen number: 1; Pharmaceutical therapy drug name: Avastin.
- Drug treatment 10: Regimen number: 2; Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 11, Route of administrations: Route of administration: Intravesical.
- Drug treatment 14: Regimen number: 2; Pharmaceutical therapy drug name: 5FU; Therapy regimen: Progression.
- Drug treatment 16: Treatment best response: Clinical Progressive Disease.
- Drug treatment 17: Pharmaceutical therapy drug name: 5-FU; Treatment best response: Clinical Progressive Disease.
- Drug treatment 20: Pharmaceutical therapy drug name: Avastin; Treatment best response: Clinical Progressive Disease.
- Drug treatment 22: Pharmaceutical therapy drug name: Erbitux; Treatment best response: Clinical Progressive Disease.
- Follow-up form 1: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form 1, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 2: Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Follow-up form 4: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,331 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,331 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 535 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-A6-2671-01A-01D-1549-01): tumor purity 0.73, ploidy 3.57, whole-genome doublings 1.
